Somatic mutation profile of tumor specimen MP2PRT-PAVYRS-TMP1-A (aliquot MP2PRT-PAVYRS-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYRS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,181 days).
Specimen MP2PRT-PAVYRS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb36b711-c217-41e4-8482-88c0f9e89756.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYRS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYRS-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/614aae54-add4-45cc-8bb0-7ac830ee9532

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZHIP | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 96/642 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1158182666, COSV57955285, COSV57956590; called by muse, mutect2, varscan2
- FAM110B | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 140/576 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64067493, COSV99058582; called by muse, mutect2, varscan2
- FHOD3 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 116/499 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs146957872, COSV57187669; called by muse, varscan2
- GRIN2A | c.4249C>T p.R1417W | Missense Mutation (SNP) | VAF 37/387 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369508378; called by muse, mutect2
- NCAM2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 133/397 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as rs751165756, COSV53058235; called by muse, mutect2, varscan2
- PCDHB2 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 42/1188 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV99165209; called by muse, mutect2
- SNTG1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs768385931, COSV52423255; called by muse, mutect2
- TNKS1BP1 | c.4238A>G p.D1413G | Missense Mutation (SNP) | VAF 121/516 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV64102902; called by muse, mutect2, varscan2
- TYR | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs561008244, COSV54479660; called by muse, mutect2, varscan2
- CHD2 | c.1711_1719+8delinsGGGG p.X571_splice | Splice Site (DEL) | VAF 41/186 reads (22%) | called by pindel, varscan2*
- TFDP1 | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 57/411 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- UBASH3A | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 28/1056 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1G | c.2997C>T p.S999= | Silent (SNP) | VAF 75/241 reads (31%) | catalogued as rs202154530, COSV61729566; called by muse, mutect2, varscan2
- DMRT3 | c.1032C>T p.A344= | Silent (SNP) | VAF 26/442 reads (6%) | catalogued as rs766101082, COSV51904706; called by muse, mutect2
- GLRA2 | c.1047G>A p.L349= | Silent (SNP) | VAF 16/402 reads (4%) | called by muse, mutect2
- OR5D18 | c.63C>T p.Y21= | Silent (SNP) | VAF 50/460 reads (11%) | catalogued as COSV61735992; called by muse, mutect2, varscan2
- SI | c.2571A>G p.T857= | Silent (SNP) | VAF 54/176 reads (31%) | catalogued as rs754848519; called by muse, mutect2, varscan2
- SULT1B1 | c.246G>A p.L82= | Silent (SNP) | VAF 20/351 reads (6%) | catalogued as rs1284518838; called by muse, mutect2
